Somatic mutation profile of tumor specimen TCGA-CN-5365-01A (aliquot TCGA-CN-5365-01A-01D-1434-08) from TCGA case TCGA-CN-5365, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 38.9 years (14,190 days).
Specimen TCGA-CN-5365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0810cd26-438d-40e6-82c5-f0e1784a3bab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5365-10A (Blood Derived Normal), aliquot TCGA-CN-5365-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/904dfd7e-6b38-4372-8e42-1ea58904ecb6

The open-access MAF lists 73 somatic variants for this specimen: 54 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/155 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 48/84 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.4171G>C p.V1391L | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100229548; called by muse, mutect2
- ACADSB | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 18/176 reads (10%) | catalogued as COSV100715325; called by muse, mutect2
- ADGRL4 | c.1461G>C p.K487N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV66066434; called by muse, mutect2, varscan2
- ADRB3 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100800015; called by muse, mutect2, varscan2
- AKAP5 | c.749T>A p.L250H | Missense Mutation (SNP) | VAF 162/268 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV100278091; called by muse, varscan2
- CADPS | c.3865C>A p.L1289I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV99341202; called by muse, mutect2, varscan2
- CDR2 | c.239A>T p.H80L | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99193576; called by muse, mutect2, varscan2
- CRK | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs776920144, COSV100315771; called by muse, mutect2, varscan2
- CSMD2 | c.4390C>T p.P1464S | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV53967559; called by muse, mutect2, varscan2
- EIF3A | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 109/398 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs150064739; called by muse, mutect2, varscan2
- EIF3A | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100974841; called by muse, mutect2, varscan2
- FAM126B | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99628300; called by muse, mutect2
- FAM47C | c.2837A>T p.K946M | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV63730729; called by muse, mutect2, varscan2
- FAT4 | c.7525G>T p.G2509C | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV58710957, COSV58713268; called by muse, mutect2
- FLG | c.7683G>T p.R2561S | Missense Mutation (SNP) | VAF 138/482 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV64245905, COSV64250535; called by muse, mutect2, varscan2
- GPR12 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67344418; called by muse, mutect2, varscan2
- GSTM2 | c.177+2T>A p.X59_splice | Splice Site (SNP) | VAF 25/162 reads (15%) | catalogued as COSV53984161; called by muse, mutect2, varscan2
- INSIG1 | c.476G>C p.R159T | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV60921278; called by muse, mutect2, varscan2
- LRFN5 | c.1343A>C p.Q448P | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV53276878; called by muse, mutect2, varscan2
- MUC16 | c.26954C>T p.A8985V | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV67459465; called by muse, mutect2, varscan2
- MUC21 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 88/644 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV66222369; called by muse, varscan2
- NKAIN2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as rs767024716, COSV63677421; called by muse, mutect2, varscan2
- NLRP8 | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV52587927, COSV52594570; called by muse, mutect2
- NPY5R | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV58454075; called by muse, mutect2, varscan2
- NYNRIN | c.3926G>A p.C1309Y | Missense Mutation (SNP) | VAF 143/312 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as COSV66845355; called by muse, mutect2, varscan2
- OR2J2 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 59/395 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.17); catalogued as rs772463705, COSV101013479; called by muse, mutect2, varscan2
- OR5L2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101004430; called by muse, mutect2, varscan2
- OR5T3 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 120/367 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57380409; called by muse, mutect2, varscan2
- PBRM1 | c.1583A>T p.N528I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.635); catalogued as COSV56268961, COSV56271832; called by muse, mutect2, varscan2
- PCDH9 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 41/123 reads (33%) | catalogued as COSV60539568; called by muse, mutect2, varscan2
- PCDHGA5 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as rs766850721, COSV53897784, COSV99548920; called by muse, mutect2, varscan2
- PTPRT | c.3065C>A p.A1022E | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62025205; called by muse, mutect2, varscan2
- RAB37 | c.506T>C p.F169S (on ENST00000392613 / NM_001006638.3; = p.F162S on NM_175738.5) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99380320; called by muse, mutect2
- SAPCD1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV100991992; called by muse, mutect2, varscan2
- SERPINB6 | c.530T>G p.L177W (on ENST00000612421 / NM_001271823.2; = p.L158W on NM_004568.6) | Missense Mutation (SNP) | VAF 47/634 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as COSV59567667, COSV59567767; called by muse, mutect2
- SIGLEC5 | c.1411G>C p.G471R | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.045); catalogued as COSV55784329; called by muse, mutect2
- SIX6 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100576558; called by muse, mutect2
- SLC22A16 | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV57935147; called by muse, mutect2, varscan2
- SLFN11 | c.2354T>C p.V785A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs747649998, COSV57700763; called by muse, mutect2, varscan2
- SLFN5 | c.2146G>T p.G716C | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs769644062, COSV55483796; called by muse, mutect2, varscan2
- STK3 | c.1468A>C p.N490H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.177); catalogued as COSV69227418; called by muse, mutect2
- SYP | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV99603169; called by muse, mutect2, varscan2
- TNFSF13B | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV65517452; called by muse, mutect2, varscan2
- TRIM69 | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.718); catalogued as rs762526755, COSV100274430; called by muse, mutect2, varscan2
- UGT2B17 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV100497315; called by muse, mutect2, varscan2
- VPS35 | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100140836; called by muse, mutect2, varscan2
- ZBBX | c.2039A>G p.D680G | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV56802641; called by muse, mutect2, varscan2
- ZNF518A | c.3875A>T p.K1292I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100283765; called by muse, mutect2, varscan2
- ACACB | c.6526_6539del p.A2176Rfs*3 | Frame Shift Del (DEL) | VAF 45/234 reads (19%) | called by mutect2, pindel, varscan2
- NF2 | c.801_802dup p.D268Vfs*29 | Frame Shift Ins (INS) | VAF 88/185 reads (48%) | called by mutect2, pindel, varscan2
- RASGRP1 | c.1961del p.G654Efs*11 | Frame Shift Del (DEL) | VAF 25/44 reads (57%) | called by mutect2, varscan2
- SAMD10 | c.145_163del p.E49Cfs*57 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- B3GNT7 | c.924C>T p.S308= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV55007236, COSV99806039; called by muse, mutect2, varscan2
- BEND4 | c.627C>T p.N209= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs574971489, COSV72468915; called by muse, mutect2, varscan2
- CCDC14 | c.2556G>A p.V852= (on ENST00000488653; = p.V804= on NM_022757.5) | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100113480; called by muse, mutect2, varscan2
- DCAF17 | c.606G>T p.G202= | Silent (SNP) | VAF 7/129 reads (5%) | catalogued as COSV100266300, COSV59830552; called by muse, mutect2
- IKZF3 | c.1128C>T p.G376= | Silent (SNP) | VAF 18/274 reads (7%) | catalogued as COSV53107673; called by muse, mutect2
- MMADHC | c.723T>A p.T241= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100307351; called by muse, mutect2, varscan2
- MUC21 | c.489C>T p.S163= | Silent (SNP) | VAF 87/565 reads (15%) | catalogued as rs906808173, COSV66222365; called by muse, varscan2
- NOTCH1 | c.813C>T p.A271= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as COSV99492232; called by muse, mutect2, varscan2
- PDE4B | c.21G>T p.V7= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as COSV58497379; called by muse, mutect2, varscan2
- PLCH1 | c.609G>A p.E203= (on ENST00000340059 / NM_001130960.2; = p.E215= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV58210854; called by muse, mutect2, varscan2
- PXN | c.1419A>G p.A473= (on ENST00000228307 / NM_001080855.3; = p.A439= on NM_002859.4) | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1294158430, COSV57222118; called by muse, mutect2, varscan2
- RIOK2 | c.1047G>C p.G349= | Silent (SNP) | VAF 48/340 reads (14%) | catalogued as COSV99300260; called by muse, varscan2
- SEMA3A | c.2163C>T p.F721= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV54862121, COSV54889735; called by muse, mutect2
- SUPT4H1 | c.45C>T p.A15= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99842865; called by muse, mutect2, varscan2
- THSD7A | c.3318C>T p.I1106= | Silent (SNP) | VAF 43/332 reads (13%) | catalogued as COSV101448924; called by muse, mutect2, varscan2
- TLK2 | c.1377T>C p.N459= (on ENST00000326270 / NM_001284333.2; = p.N437= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV58306633; called by muse, mutect2, varscan2
- VDAC1 | c.156C>G p.T52= | Silent (SNP) | VAF 32/204 reads (16%) | catalogued as COSV99527348; called by muse, mutect2, varscan2
- RNF217 | c.1116+2794C>A | Intron (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99255384; called by muse, mutect2, varscan2
- SNORD116-24 | n.34G>C | RNA (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
